Gene-level copy-number profile of tumor specimen TCGA-L5-A4OX-01A from TCGA case TCGA-L5-A4OX, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIB; Tumor grade: GX; Age at diagnosis: 60.3 years (22,015 days).
Specimen TCGA-L5-A4OX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.b7689dc1-b7ac-41d0-9880-ba7415daef61.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-L5-A4OX-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f3651b8e-e6b4-41f1-85c4-53f7bf011575

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 8,138; copy number 2: 46,745; copy number 3: 3,591; copy number 4: 1,097; copy number 5: 140; copy number 8: 7; copy number 22: 63; copy number 30: 18.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-L5-A4OX-01A-21D-A28A-01): tumor purity 0.71, ploidy 1.9, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:59,809,269–59,811,310, 1 gene: AC093418.1.
- chr4:91,603,275–91,605,292, 1 gene: AC110774.1.
- chr21:34,836,286–35,139,222, 2 genes: AP000331.1, AF015262.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 228 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:98,761,098–99,490,035, 18 genes, copy number 5: LINC02611, RNU4-84P, CRACDL, RNU7-46P, TSGA10, SMC3P1, AC079447.1, C2orf15, LIPT1, AC092587.1, MITD1, MRPL30, LYG2, LYG1, TXNDC9, EIF5B, REV1, AC018690.1.
- chr2:102,736,905–108,226,331, 94 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr17:30,068,632–30,577,000, 27 genes, copy number 5: AC104996.2, AC104984.2, NSRP1, hsa-mir-423, MIR423, MIR3184, AC104984.3, AC104984.5, SLC6A4, AC104984.1, AC104984.4, SNORD63, BLMH, RNU6-1267P, TMIGD1, Y_RNA, RNU6-990P, CPD, GOSR1, ALOX12P1, AC011840.3, AC011840.5, TBC1D29P, AC011840.4, AC011840.2, KRT17P3, AC011840.1.
- chr17:30,600,796–30,615,980, 1 gene, copy number 5: SMURF2P1.
- chr17:40,921,430–41,977,740, 88 genes, copy number 8–30 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 8,138. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
